Gene-level copy-number profile of tumor specimen TCGA-E1-A7YD-01A from TCGA case TCGA-E1-A7YD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 57.5 years (21,020 days).
Specimen TCGA-E1-A7YD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.6b494b95-ae67-42dc-8755-f851b6b866c5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-A7YD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a6522f9-59b7-4ebc-9e61-2975b0022ab7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 12; copy number 2: 12,200; copy number 3: 23,639; copy number 4: 20,139; copy number 5: 3,265; copy number 6: 334; copy number 7: 25; copy number 8: 15; copy number 10: 82; copy number 12: 29; copy number 29: 47; copy number 34: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-A7YD-01A-11D-A349-01): tumor purity 0.79, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 221 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–203,744,081, 1 gene, copy number 29 (within-gene range 4–29): ATP2B4.
- chr1:203,729,581–203,955,780, 11 genes, copy number 29: SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3.
- chr1:204,346,776–204,685,738, 12 genes, copy number 7 (within-gene range 4–7): AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2.
- chr4:52,872,982–58,118,070, 103 genes, copy number 10–12 (within-gene range 5–12) (broad region; genes not listed).
- chr4:78,669,690–80,336,680, 22 genes, copy number 8–10: AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P, LINC01088, NAA11, GK2, LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8, FGF5.
- chr4:80,386,178–80,388,716, 1 gene, copy number 8: AC105917.1.
- chr7:13,854,355–14,974,777, 8 genes, copy number 7 (within-gene range 6–7): AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1.
- chr7:54,330,670–55,713,252, 28 genes, copy number 7–34 (within-gene range 6–34): LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr12:57,415,296–57,797,554, 35 genes, copy number 29 (within-gene range 3–29): RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
